Somatic mutation profile of tumor specimen TCGA-3H-AB3T-01A (aliquot TCGA-3H-AB3T-01A-11D-A39R-32) from TCGA case TCGA-3H-AB3T, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mesothelioma, biphasic, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 79.2 years (28,925 days).
Specimen TCGA-3H-AB3T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60da6046-d32e-4d0c-8578-530cb6d53646.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3H-AB3T-10A (Blood Derived Normal), aliquot TCGA-3H-AB3T-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a977ef6-8ef8-40dd-aa15-e86d5b94c36d

The open-access MAF lists 41 somatic variants for this specimen: 29 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 10, Frame Shift Del 3, Intron 1, Nonsense Mutation 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACRBP | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1297808810, COSV57525052; called by muse, mutect2, varscan2
- BAP1 | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | catalogued as COSV56235079; called by muse, mutect2, varscan2
- CERS2 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as rs1194312617; called by muse, mutect2, varscan2
- FLG | c.9628C>T p.R3210C | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as rs571141981, COSV64246321; called by muse, mutect2, varscan2
- KCNJ12 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs781939302, COSV59164351, COSV59176689; called by muse, mutect2
- LATS1 | c.2494G>T p.D832Y | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53600559; called by muse, mutect2, varscan2
- NLRP9 | c.1985G>A p.R662Q | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs537827210, COSV60462558; called by muse, mutect2, varscan2
- PCSK1 | c.1693G>A p.G565S | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100226966; called by muse, mutect2, varscan2
- PLEKHG1 | c.872A>T p.N291I | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62052300; called by muse, mutect2, varscan2
- PLEKHM1 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.932); catalogued as rs1346167214; called by muse, mutect2, varscan2
- PROKR2 | c.495G>C p.M165I | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); catalogued as COSV54086643; called by muse, mutect2, varscan2
- RAD50 | c.1019A>G p.N340S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.085); catalogued as rs776934742; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN2A | c.5437A>G p.I1813V | Missense Mutation (SNP) | VAF 39/205 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs1415735621; called by muse, mutect2, varscan2
- SRGAP3 | c.2510C>T p.S837F | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1439321820, COSV64532070; called by muse, mutect2, varscan2
- TBRG4 | c.500C>G p.S167W | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51832016; called by muse, mutect2, varscan2
- ZNF148 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV100642066; called by muse, mutect2, varscan2
- AXIN2 | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- BAAT | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- HECTD1 | c.1451A>T p.D484V | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.67); called by muse, mutect2
- JARID2 | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, mutect2
- KLHL25 | c.1005del p.S336Qfs*9 | Frame Shift Del (DEL) | VAF 26/103 reads (25%) | called by mutect2, pindel, varscan2
- LATS2 | c.1960_1974delinsTTAAT p.N654Lfs*40 | Frame Shift Del (DEL) | VAF 23/101 reads (23%) | called by pindel, varscan2*
- LYPD3 | c.710_713del p.P237Lfs*26 | Frame Shift Del (DEL) | VAF 36/160 reads (23%) | called by mutect2, pindel, varscan2
- NRDE2 | c.2318_2321delinsT p.E773_P774delinsV | In Frame Del (DEL) | VAF 17/135 reads (13%) | called by pindel, varscan2*
- PRR14 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RARA | c.976A>T p.T326S | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STAT1 | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM169 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR59 | c.122T>A p.I41N | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- ACTL10 | c.441G>A p.A147= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs972239745; called by muse, mutect2, varscan2
- GOLGB1 | c.1920G>A p.A640= | Silent (SNP) | VAF 27/159 reads (17%) | catalogued as rs112783488, COSV61461418; called by muse, mutect2, varscan2
- KMT2A | c.10740C>T p.G3580= | Silent (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
- NTAQ1 | c.42C>G p.A14= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV54873736; called by muse, mutect2, varscan2
- NYX | c.474G>A p.L158= | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as COSV61182137; called by muse, mutect2, varscan2
- OSBPL10 | c.222G>A p.E74= | Silent (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- RAB17 | c.87C>T p.S29= | Silent (SNP) | VAF 34/173 reads (20%) | catalogued as rs776807116, COSV52815528; called by muse, mutect2, varscan2
- STK35 | c.573T>C p.P191= | Silent (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- TAF10 | c.654C>T p.T218= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV54990859; called by muse, mutect2, varscan2
- TF | c.864G>A p.Q288= | Silent (SNP) | VAF 20/85 reads (24%) | called by muse, mutect2, varscan2
- LRRC55 | chr11:57181947 T>C | 5'Flank (SNP) | VAF 30/152 reads (20%) | called by muse, mutect2, varscan2
- MEGF6 | c.481+19087G>A | Intron (SNP) | VAF 16/70 reads (23%) | catalogued as rs753091537; called by muse, mutect2, varscan2
